Somatic mutation profile of tumor specimen ALCH-ABZH-TTP1-A (aliquot ALCH-ABZH-TTP1-A-2-0-D-A491-36) from ALCHEMIST case ALCH-ABZH, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 61.9 years (22,599 days).
Specimen ALCH-ABZH-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 36873275-0cc4-400b-8c22-f03d03477048.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ABZH-NB1-A (Blood Derived Normal), aliquot ALCH-ABZH-NB1-A-1-0-D-A491-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4e242e76-f199-42a4-a833-9bfdeb828c6c

The open-access MAF lists 40 somatic variants for this specimen: 20 protein-altering or splice-affecting, 13 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 13, Intron 4, Nonsense Mutation 2, 5'Flank 2, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CLSTN1 | c.1270G>A p.G424R (on ENST00000377298 / NM_001009566.3; = p.G414R on NM_014944.4) | Missense Mutation (SNP) | VAF 46/327 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.879); catalogued as rs369660230; called by muse, mutect2, varscan2
- FLG2 | c.4333C>T p.Q1445* | Nonsense Mutation (SNP) | VAF 84/1376 reads (6%) | catalogued as COSV66169044; called by muse, mutect2
- JAK1 | c.859G>C p.E287Q | Missense Mutation (SNP) | VAF 20/558 reads (4%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.669); catalogued as COSV61089934; called by muse, mutect2
- PTPRD | c.2621C>A p.S874Y | Missense Mutation (SNP) | VAF 16/402 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.285); catalogued as COSV61956398; called by muse, mutect2
- SUN3 | c.46C>T p.R16C | Missense Mutation (SNP) | VAF 26/403 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.043); catalogued as rs969807123; called by muse, mutect2
- ACACB | c.7130A>G p.N2377S | Missense Mutation (SNP) | VAF 10/236 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.001); called by muse, mutect2
- DNPEP | c.299T>C p.L100P | Missense Mutation (SNP) | VAF 26/384 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.067); called by muse, mutect2
- G6PC2 | c.518C>T p.T173I | Missense Mutation (SNP) | VAF 24/709 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); called by muse, mutect2
- MED17 | c.796C>G p.P266A | Missense Mutation (SNP) | VAF 38/1080 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.054); called by muse, mutect2
- MXRA8 | c.727G>A p.V243M | Missense Mutation (SNP) | VAF 14/303 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2
- PIGW | c.1008G>C p.L336F | Missense Mutation (SNP) | VAF 13/258 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2
- PRR35 | c.1033G>C p.E345Q | Missense Mutation (SNP) | VAF 16/540 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.563); called by muse, mutect2
- RPL34 | c.106A>G p.K36E | Missense Mutation (SNP) | VAF 38/613 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.686); called by muse, mutect2
- SAXO2 | c.207G>C p.E69D | Missense Mutation (SNP) | VAF 15/460 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.154); called by muse, mutect2
- SLFN12 | c.895T>C p.C299R | Missense Mutation (SNP) | VAF 53/675 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.009); called by muse, mutect2
- STAB2 | c.1937A>T p.Y646F | Missense Mutation (SNP) | VAF 20/448 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.167); called by muse, mutect2
- USP30 | c.1499A>T p.E500V | Missense Mutation (SNP) | VAF 31/368 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- VPS13B | c.5134G>A p.E1712K | Missense Mutation (SNP) | VAF 28/582 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.257); called by muse, mutect2
- ZFPM1 | c.2973_2974delinsT p.H992Tfs*14 | Frame Shift Del (DEL) | VAF 6/45 reads (13%) | called by pindel, varscan2*
- ZNF135 | c.353G>A p.W118* (on ENST00000313434 / NM_001289401.2; = p.W130* on NM_003436.4) | Nonsense Mutation (SNP) | VAF 21/482 reads (4%) | called by muse, mutect2
- DNAH14 | c.4329A>G p.A1443= (on ENST00000445597; = p.A1848= on NM_001367479.1) | Silent (SNP) | VAF 11/246 reads (4%) | called by muse, mutect2
- FKTN | c.270C>G p.V90= | Silent (SNP) | VAF 24/533 reads (5%) | catalogued as COSV99795683; called by muse, mutect2
- GABRB1 | c.1248C>T p.R416= | Silent (SNP) | VAF 25/307 reads (8%) | catalogued as rs78444131, COSV54995191; called by muse, mutect2
- GCAT | c.252G>A p.V84= | Silent (SNP) | VAF 22/620 reads (4%) | called by muse, mutect2
- HSD3B1 | c.750A>C p.R250= | Silent (SNP) | VAF 20/406 reads (5%) | called by muse, mutect2
- INO80 | c.474C>T p.H158= | Silent (SNP) | VAF 31/576 reads (5%) | called by muse, mutect2
- KRTAP5-5 | c.690C>T p.P230= | Silent (SNP) | VAF 10/284 reads (4%) | catalogued as rs183750160; called by muse, mutect2
- LRRC38 | c.300C>T p.F100= | Silent (SNP) | VAF 26/694 reads (4%) | called by muse, mutect2
- PHEX | c.562C>T p.L188= | Silent (SNP) | VAF 37/1064 reads (3%) | called by muse, mutect2
- SLC35B3 | c.723C>T p.V241= | Silent (SNP) | VAF 9/164 reads (5%) | called by muse, mutect2
- TSPEAR | c.1020C>T p.L340= | Silent (SNP) | VAF 38/668 reads (6%) | called by muse, mutect2
- ZNF516 | c.3105G>T p.A1035= | Silent (SNP) | VAF 16/146 reads (11%) | called by muse, mutect2, varscan2
- ZXDB | c.1185C>T p.C395= | Silent (SNP) | VAF 26/500 reads (5%) | catalogued as rs1368222086; called by muse, mutect2
- ATP9B | c.558+1640A>G | Intron (SNP) | VAF 11/60 reads (18%) | called by muse, mutect2, varscan2
- CANX | chr5:179698553 C>T | 5'Flank (SNP) | VAF 16/418 reads (4%) | called by muse, mutect2
- FLRT2 | chr14:85528800 G>C | 5'Flank (SNP) | VAF 21/196 reads (11%) | called by muse, mutect2
- MASP1 | c.1304-5244C>G | Intron (SNP) | VAF 12/364 reads (3%) | called by muse, mutect2
- NANOGP1 | n.914G>A | RNA (SNP) | VAF 26/670 reads (4%) | called by muse, mutect2
- PPP2R2B | c.1052+840G>C | Intron (SNP) | VAF 17/564 reads (3%) | called by muse, mutect2
- SCD5 | c.569+19700C>T | Intron (SNP) | VAF 22/583 reads (4%) | called by muse, mutect2
